CCDI case PBBVVI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/b401ba31-0293-4a8f-8ddc-486006efa872

Demographics
Sex at birth: male; Race: black or african american; Vital status: Alive.

Diagnoses (1)
1. Neoplasm, malignant, uncertain whether primary or metastatic: ICD-O-3 morphology code: 8000/9; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 0.8 years (292 days).

Biospecimens (3 samples)
- Sample 0DLRHE: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DLRHZ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DLRIB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
